Somatic mutation profile of tumor specimen MBCProject_0178_T1_WES (aliquot MBCProject_0178_T1_WES_1) from CMI case MBCProject_0178, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 37.1 years (13,536 days).
Specimen MBCProject_0178_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58365f4b-a0a8-426a-be64-11189d5c69b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0178_SALIVA (Saliva), aliquot MBCProject_0178_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ce2ab42-9f7e-4207-8962-134c60573b41

The open-access MAF lists 120 somatic variants for this specimen: 82 protein-altering or splice-affecting, 28 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 28, Intron 7, Nonsense Mutation 2, RNA 1, 5'UTR 1, 3'Flank 1, Nonstop Mutation 1, Frame Shift Del 1, Frame Shift Ins 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 129/259 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRA3 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.145); catalogued as rs770806145, COSV100529186, COSV100529645; called by muse, mutect2, varscan2
- APC2 | c.2855C>G p.S952W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV52017315; called by muse, mutect2, varscan2
- ARL16 | c.134-5C>T | Splice Region (SNP) | VAF 23/77 reads (30%) | catalogued as rs1181255488, COSV61267129; called by muse, mutect2, varscan2
- C1GALT1 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs189360329, COSV56179913; called by muse, mutect2, varscan2
- CCDC136 | c.2894G>A p.R965H | Missense Mutation (SNP) | VAF 45/288 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs779042205; called by muse, mutect2, varscan2
- CTNND2 | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 49/398 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs750967819, COSV100476170, COSV58876698; called by muse, mutect2, varscan2
- FRYL | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs765153279, COSV51942336, COSV51963863; called by muse, mutect2, varscan2
- GDE1 | c.77G>C p.R26P | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100783197; called by muse, mutect2, varscan2
- JAK3 | c.2444C>T p.T815M | Missense Mutation (SNP) | VAF 188/449 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs200579386, COSV101512898, COSV99070387; called by muse, mutect2, varscan2
- KDM3B | c.2344G>C p.D782H | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.224); catalogued as COSV58691360; called by muse, mutect2
- LRRTM1 | c.816G>T p.E272D | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.085); catalogued as COSV99701961; called by muse, mutect2, varscan2
- MAN2A2 | c.2937_2939del p.N979del | In Frame Del (DEL) | VAF 17/157 reads (11%) | catalogued as rs1373527871; called by pindel, varscan2
- MIA3 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100719333; called by muse, mutect2
- MMP20 | c.886T>G p.C296G | Missense Mutation (SNP) | VAF 249/415 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99497800; called by muse, mutect2, varscan2
- MYO1G | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs748813866, COSV51854462; called by muse, mutect2
- NOS3 | c.1404C>A p.F468L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99872131; called by muse, mutect2
- OR4C6 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.213); catalogued as rs771596913, COSV100051507; called by muse, mutect2, varscan2
- PABPC1 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV59401924; called by muse, mutect2
- PPP4R4 | c.941C>G p.S314C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58557051; called by muse, mutect2
- SMARCA1 | c.281G>T p.R94I | Missense Mutation (SNP) | VAF 30/458 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100946517; called by muse, mutect2
- STRIP1 | c.1290G>C p.E430D | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as COSV100874012; called by muse, mutect2, varscan2
- TAF1L | c.5045C>T p.S1682F | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs1202949606; called by muse, mutect2, varscan2
- TERF2 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 42/588 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54748236; called by muse, mutect2
- TP73 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100601157, COSV60699868; called by muse, mutect2, varscan2
- TPRN | c.989C>G p.S330C | Missense Mutation (SNP) | VAF 24/377 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757165154, COSV58809159; called by muse, mutect2
- TRAP1 | c.1987G>C p.G663R | Missense Mutation (SNP) | VAF 48/375 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs567924524; called by muse, mutect2, varscan2
- TUBGCP3 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); catalogued as rs1201124030, COSV56185854; called by muse, mutect2
- ABCC1 | c.3193G>A p.E1065K | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHCY | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 23/504 reads (5%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.135); called by muse, mutect2
- ATP1B4 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 51/183 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- BAHCC1 | c.5164G>A p.E1722K | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- CAND2 | c.1266G>C p.Q422H (on ENST00000456430 / NM_001162499.2; = p.Q329H on NM_012298.3) | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CARD6 | c.1966C>T p.Q656* | Nonsense Mutation (SNP) | VAF 31/202 reads (15%) | called by muse, mutect2, varscan2
- COL6A3 | c.6244C>G p.Q2082E | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CREBZF | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CTH | c.745C>G p.P249A | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- DNAAF2 | c.2071C>G p.H691D | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EEPD1 | c.1465C>G p.L489V | Missense Mutation (SNP) | VAF 43/302 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ENO4 | c.905_935del p.I302Nfs*17 (on ENST00000622726; = p.I301Nfs*17 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 24/157 reads (15%) | called by mutect2, pindel
- GATA3 | c.1324_*41del | Nonstop Mutation (DEL) | VAF 14/82 reads (17%) | called by mutect2, pindel
- H2AJ | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 67/285 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- HEATR1 | c.6103G>C p.E2035Q | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.071); called by muse, mutect2
- HMGB1 | c.247G>C p.G83R | Missense Mutation (SNP) | VAF 39/428 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.421); called by muse, mutect2
- IGBP1P2 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2
- IGSF1 | c.2644G>T p.G882C | Missense Mutation (SNP) | VAF 26/524 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IVNS1ABP | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- KCTD9 | c.21C>G p.F7L | Missense Mutation (SNP) | VAF 63/255 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- KIF21B | c.3122C>G p.S1041C | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- LMLN2 | c.65G>C p.R22P | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- MALRD1 | c.3154G>C p.D1052H | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MID1 | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2
- NBEA | c.6400G>A p.D2134N | Missense Mutation (SNP) | VAF 83/327 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- NBPF9 | c.1362G>C p.Q454H | Missense Mutation (SNP) | VAF 95/491 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- NPHS2 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 53/300 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NR4A3 | c.1190G>T p.C397F | Missense Mutation (SNP) | VAF 10/273 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.162); called by muse, mutect2
- NWD1 | c.4454G>C p.S1485T | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OSTM1 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1654C>T p.P552S (on ENST00000259318 / NM_001136562.3; = p.P783S on NM_007203.5) | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); called by muse, mutect2
- PCDHB15 | c.1951C>G p.P651A | Missense Mutation (SNP) | VAF 79/427 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- PHIP | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PKN1 | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- PLEKHG1 | c.3337G>C p.E1113Q | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2
- POGLUT3 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.917); called by muse, mutect2
- POU2F2 | c.630C>G p.F210L (on ENST00000526816 / NM_001207025.3; = p.F194L on NM_002698.5) | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2
- SLC38A4 | c.1517C>A p.T506N | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC7A10 | c.56C>A p.S19* | Nonsense Mutation (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- SLF2 | c.36C>A p.F12L | Missense Mutation (SNP) | VAF 67/368 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SLX4 | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 148/460 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SSC5D | c.1078G>C p.G360R | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STMND1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.028); called by muse, varscan2
- STRA8 | c.606G>C p.Q202H (on ENST00000275764; = p.Q180H on NM_182489.2) | Missense Mutation (SNP) | VAF 25/313 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- TACC2 | c.5143G>C p.E1715Q | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- TJP1 | c.407_408dup p.H137Yfs*55 | Frame Shift Ins (INS) | VAF 31/74 reads (42%) | called by mutect2, pindel
- TMCO4 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- WDFY4 | c.4291C>G p.L1431V | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2
- WDSUB1 | c.1216G>C p.D406H | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZMIZ1 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 39/332 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF462 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- ZNF584 | c.144G>C p.E48D | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF696 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZNF710 | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.843); called by muse, varscan2
- ARL2BP | c.339C>A p.L113= | Silent (SNP) | VAF 33/264 reads (13%) | called by muse, mutect2, varscan2
- B3GNT9 | c.456C>T p.R152= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1028022794; called by muse, mutect2
- DERL1 | c.42C>T p.I14= | Silent (SNP) | VAF 45/318 reads (14%) | called by muse, mutect2, varscan2
- DNAH10 | c.4801C>T p.L1601= (on ENST00000409039; = p.L1540= on NM_207437.3) | Silent (SNP) | VAF 9/166 reads (5%) | called by muse, mutect2
- EGR3 | c.186G>A p.E62= | Silent (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2
- ELMO2 | c.1986C>G p.L662= | Silent (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- FEM1A | c.1443G>A p.L481= | Silent (SNP) | VAF 15/158 reads (9%) | called by muse, mutect2
- FOXP4 | c.1011G>C p.R337= (on ENST00000307972 / NM_001012426.1; = p.R336= on NM_138457.3) | Silent (SNP) | VAF 16/320 reads (5%) | catalogued as rs1323033501; called by muse, mutect2
- GALNT18 | c.825C>T p.I275= | Silent (SNP) | VAF 41/299 reads (14%) | catalogued as rs370735069; called by muse, mutect2, varscan2
- GLMP | c.192C>T p.T64= | Silent (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- HMCN2 | c.12076C>T p.L4026= | Silent (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- IGFALS | c.1077C>T p.L359= | Silent (SNP) | VAF 50/338 reads (15%) | catalogued as rs375344055; called by muse, mutect2, varscan2
- ISOC2 | c.171G>A p.L57= | Silent (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- KCNQ2 | c.1209C>G p.L403= (on ENST00000359125 / NM_172107.4; = p.L393= on NM_004518.6) | Silent (SNP) | VAF 13/171 reads (8%) | catalogued as rs752280961; ClinVar: likely benign; called by muse, mutect2
- KLF15 | c.1014C>G p.L338= | Silent (SNP) | VAF 11/187 reads (6%) | called by muse, mutect2
- MRPS28 | c.156C>T p.F52= | Silent (SNP) | VAF 32/278 reads (12%) | catalogued as rs1345731655; called by muse, mutect2, varscan2
- NOXO1 | c.315G>C p.R105= (on ENST00000397280 / NM_172168.3; = p.R99= on NM_144603.4) | Silent (SNP) | VAF 10/256 reads (4%) | called by muse, mutect2
- NRCAM | c.2292G>A p.V764= (on ENST00000379028 / NM_001371124.1; = p.V748= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 31/280 reads (11%) | called by muse, mutect2, varscan2
- OR2D3 | c.939C>G p.V313= | Silent (SNP) | VAF 37/226 reads (16%) | called by muse, mutect2, varscan2
- PGAP3 | c.939A>G p.S313= | Silent (SNP) | VAF 190/4064 reads (5%) | called by muse, mutect2
- PGAP3 | c.525C>G p.V175= | Silent (SNP) | VAF 594/3204 reads (19%) | called by muse, varscan2
- PLA2G6 | c.1383G>C p.R461= | Silent (SNP) | VAF 31/393 reads (8%) | called by muse, mutect2
- PRR11 | c.756G>A p.S252= | Silent (SNP) | VAF 64/686 reads (9%) | catalogued as rs776930887; called by muse, mutect2
- SDHD | c.435C>T p.H145= | Silent (SNP) | VAF 62/267 reads (23%) | catalogued as rs200062830, COSV100978965; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM132D | c.3036C>T p.I1012= | Silent (SNP) | VAF 29/179 reads (16%) | catalogued as COSV67159948; called by muse, mutect2, varscan2
- TNFSF18 | c.507C>A p.T169= | Silent (SNP) | VAF 23/161 reads (14%) | called by muse, mutect2, varscan2
- UPF1 | c.2157C>T p.L719= (on ENST00000599848 / NM_001297549.2; = p.L708= on NM_002911.4) | Silent (SNP) | VAF 10/166 reads (6%) | catalogued as COSV53193417; called by muse, mutect2
- VWCE | c.1959C>T p.I653= | Silent (SNP) | VAF 13/164 reads (8%) | catalogued as rs1196926589; called by muse, mutect2
- ATP6V1B2 | chr8:20225324 C>T | 3'Flank (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- FAS | c.505+28C>G | Intron (SNP) | VAF 35/285 reads (12%) | called by muse, mutect2, varscan2
- FBXO8 | c.456+3573C>G | Intron (SNP) | VAF 14/312 reads (4%) | called by muse, mutect2
- HILPDA | c.-180G>A | 5'UTR (SNP) | VAF 42/770 reads (5%) | catalogued as rs1459008406; called by muse, mutect2
- LHX6 | c.793-61C>G | Intron (SNP) | VAF 11/126 reads (9%) | catalogued as rs1213249325; called by muse, mutect2
- LINC00243 | n.630T>C | RNA (SNP) | VAF 102/287 reads (36%) | called by muse, mutect2, varscan2
- LRRC74A | c.217+238G>A | Intron (SNP) | VAF 70/232 reads (30%) | catalogued as rs771934942; called by muse, mutect2, varscan2
- PDE6A | c.2274+26G>A | Intron (SNP) | VAF 13/327 reads (4%) | called by muse, mutect2
- SHISA5 | c.314+2139C>G | Intron (SNP) | VAF 36/65 reads (55%) | called by muse, mutect2, varscan2
- UBE2O | c.2810-31G>C | Intron (SNP) | VAF 39/97 reads (40%) | called by muse, mutect2, varscan2
